Somatic mutation profile of tumor specimen 0D9CLC from CCDI case PBBIRM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 7.7 years (2,806 days).
Specimen 0D9CLC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a37a32e-9878-40ee-a8a6-0fd883098892.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9CLN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bf5ec54-ff3d-4e3c-aa00-5a3d3be73c54

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 1, 5'UTR 1, Intron 1, Frame Shift Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 115/246 reads (47%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 206/417 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1517T>C p.I506T (on ENST00000399959; = p.I507T on NM_001356.5) | Missense Mutation (SNP) | VAF 176/403 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs797045024, CM158023; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 188/378 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by muse, mutect2, varscan2
- CNKSR2 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV99669469; called by muse, mutect2, varscan2
- EVC | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 209/488 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs779915989, CM098921; called by muse, mutect2, varscan2
- KMT2D | c.5163del p.S1722Vfs*9 | Frame Shift Del (DEL) | VAF 185/503 reads (37%) | catalogued as COSV99040068; called by mutect2, pindel, varscan2
- OR2B11 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 223/463 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59509779; called by muse, mutect2, varscan2
- PPL | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 132/248 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1259900437; called by muse, mutect2, varscan2
- DDX3X | c.1022+5G>C | Splice Region (SNP) | VAF 197/407 reads (48%) | called by muse, mutect2, varscan2
- NBEA | c.8390G>A p.S2797N | Missense Mutation (SNP) | VAF 165/363 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRSS45P | c.717A>C p.S239= | Silent (SNP) | VAF 167/364 reads (46%) | catalogued as COSV70578126; called by muse, mutect2, varscan2
- SLC35D3 | c.849C>T p.F283= | Silent (SNP) | VAF 213/223 reads (96%) | catalogued as COSV59377475; called by muse, mutect2, varscan2
- ATF7IP2 | c.*10A>G | 3'UTR (SNP) | VAF 75/150 reads (50%) | catalogued as rs1300209206; called by muse, mutect2, varscan2
- CARD19 | c.-19C>A | 5'UTR (SNP) | VAF 193/414 reads (47%) | called by muse, mutect2, varscan2
- IRF7 | c.433_433+8dup | Intron (INS) | VAF 176/434 reads (41%) | called by mutect2, varscan2
